Surgical pathology report (de-identified scan), TCGA case TCGA-RP-A6K9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RP-A6K9-06A (Metastatic).

Pathology Report

Date of Surgery:

Diagnosis: Metastatic Melanoma, posterior skull and soft tissue

Microscopic Description:

Histologic sections demonstrate a poorly cohesive malignant neoplasm comprised of markedly pleomorphic cells which often contain fine granular melanotic pigment, consistent with a metastatic melanoma. Areas of the tumor are seen surrounded by and invading skeletal muscle, nerve and fibrous tissue. The tumor is also seen infiltrating between fragments of trabecular bone.

ICD-O-3

Melanoma, malignant NOS
8720/3

Site: Bone of skull, face
and associated joints
C41.0
JW 6/28/13

Source: NCI Genomic Data Commons file 223f781d-0841-4326-bb15-fee4ff8a0866 (TCGA-RP-A6K9.D5597CA4-9FD6-49BA-AC66-B6BFAAA1592A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).